Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA3X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA3X-01A (Primary Tumor).

Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component

Surgical Pathology

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

*ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
653.9
JW 4/11/14*

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (SEE COMMENT)

COMMENT: Due to poor orientation, depth of invasion cannot be accurately evaluated, however, there appears to be at least 5.0 mm of invasion.

"I have personally reviewed the resident's preliminary interpretation and all specimen preparations and have personally issued this report."

Pertinent Clinical Information

Not given.

Gross Description

Specimen is received in one part labeled with the patient's name and medical record number.

Received in formalin and labeled "CERVICAL BIOPSY" are multiple tan-pink, rubbery portions of soft tissue measuring 3.0 x 2.0 x 1.0 cm.

Representative sections are submitted for TCGA and the remaining tissue is submitted in its entirety in cassettes A1-A3.

Pathologists' Assistant

Microscopic Description

Performed.

Pathology Resident

Electronically Signed Out

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order

) on

- Order Result History Report.

Source: NCI Genomic Data Commons file 37bffa98-947a-4c2e-9c6d-7e296adaa206 (TCGA-MA-AA3X.FE614842-9700-472D-B1D8-F2DFF940D489.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).